TCGA case TCGA-DK-A3IQ — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e44f60ec-66c4-45a2-a003-0a1faf1d6e03

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 74 years; Vital status: Dead; Days to death: 539 days (1.5 years).

Diagnoses (5)
1. Transitional cell carcinoma (the primary disease): ICD-O-3 morphology code: 8120/3; ICD-10 code: C67.4; Tissue or organ of origin: Posterior wall of bladder; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 74.5 years (27,194 days); Year of diagnosis: 2011; Method of diagnosis: Surgical Resection; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 539 days (1.5 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 14.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Days to treatment start: 277 days; Days to treatment end: 319 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Days to treatment start: 277 days; Days to treatment end: 417 days (1.1 years); Treatment outcome: Stable Disease.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Papillary renal cell carcinoma: ICD-O-3 morphology code: 8260/3; Tissue or organ of origin: Kidney, NOS; Laterality: Left; Classification of tumor: Prior primary.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Metastasis of diagnosis 1 (Transitional cell carcinoma), site: Bone, NOS. Age at diagnosis: 75.1 years (27,444 days); Days to diagnosis: 250 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
4. Recurrence of diagnosis 1 (Transitional cell carcinoma), site: Connective, subcutaneous and other soft tissues, NOS. Age at diagnosis: 75.1 years (27,444 days); Days to diagnosis: 250 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.
5. Recurrence of diagnosis 1 (Transitional cell carcinoma), site: Lymph node, NOS. Age at diagnosis: 75.1 years (27,444 days); Days to diagnosis: 250 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (5 entries)
- Day 250 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 250 days.
- Day 250 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Connective, subcutaneous and other soft tissues, NOS; Days to recurrence: 250 days.
- Day 250 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Lymph node, NOS; Days to recurrence: 250 days.
- Days to follow up: 319 days; Disease response: With Tumor.
- Days to follow up: 539 days (1.5 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 75.4 kg; Height: 173 cm; BMI: 25.2.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 40.
- Occupation type: Manufacturing, Mining, Construction and Distribution Managers.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Colorectal Cancer.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Lung Cancer.
- Relative with cancer history: yes; Relationship type: Brother; Relationship primary diagnosis: Kidney Cancer.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer.
- Relative with cancer history: yes; Relationship type: Brother; Relationship primary diagnosis: Multiple Myeloma.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DK-A3IQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 280 mg.
  Slide TCGA-DK-A3IQ-01A-03-TSC: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 20; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DK-A3IQ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DK-A3IQ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: With tumor; Occupation current: Retired; Occupation primary: Real Estate Developer; Occupation primary industry: Real Estate; Tobacco smoking history indicator: 3; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Papillary; Anatomic organ subdivision: Wall Posterior; Method initial path diagnosis: Transurethral resection (TURBT); Lymph nodes examined: Yes; Incidental prostate cancer indicator: No.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome first course: Complete Remission/Response.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Kidney; Other malignancy histological type: Kidney Papillary Renal Cell Carcinoma.

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy: Patient was previously diagnosed with kidney papillary renal cell cancer. No radiation or systemic chemotherapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 539 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 539 days; disease-free interval: event (new tumor event after initially disease-free), 250 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 250 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DK-A3IQ-01A-31D-A20B-01): tumor purity 0.35, ploidy 1.84, whole-genome doublings 0.
